Somatic mutation profile of tumor specimen MMRF_2708_1_BM_CD138pos (aliquot MMRF_2708_1_BM_CD138pos_T1_KHS5U_L14442) from MMRF case MMRF_2708, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 48.2 years (17,588 days).
Specimen MMRF_2708_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a6fd88e6-2adf-4151-b136-6974d8defe43.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2708_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2708_1_PB_WBC_C2_KHS5U_L14443; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2d3f7785-cb24-43f0-b0d7-cb1a8212ec90

The open-access MAF lists 119 somatic variants for this specimen: 53 protein-altering or splice-affecting, 13 silent, 53 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, 3'UTR 35, Silent 13, Intron 9, 5'UTR 3, 3'Flank 2, Splice Region 2, 5'Flank 2, RNA 2, Frame Shift Del 1, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.9017C>T p.A3006V | Missense Mutation (SNP) | VAF 9/193 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1319582645, COSV53760437; ClinVar: uncertain significance; called by muse, mutect2
- C11orf65 | c.732G>A p.E244= | Splice Region (SNP) | VAF 48/117 reads (41%) | catalogued as rs750354487; called by muse, mutect2, varscan2
- CABS1 | c.541C>G p.R181G | Missense Mutation (SNP) | VAF 105/233 reads (45%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs761637105, COSV56733727; called by muse, mutect2, varscan2
- CFAP61 | c.2647G>A p.E883K | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV55623751; called by muse, mutect2
- CLNK | c.58C>T p.Q20* | Nonsense Mutation (SNP) | VAF 13/36 reads (36%) | catalogued as rs373786543; called by mutect2, varscan2
- COL18A1 | c.3070G>A p.A1024T (on ENST00000359759 / NM_130444.3; = p.A789T on NM_030582.4) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.723); catalogued as rs552119369; called by muse, varscan2
- ECEL1 | c.554G>A p.R185H | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.88); catalogued as rs1353459461; called by muse, mutect2, varscan2
- FEM1A | c.1346G>A p.R449Q | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.197); catalogued as rs1327932096, COSV54164478; called by muse, mutect2, varscan2
- GYPC | c.127G>A p.G43R | Missense Mutation (SNP) | VAF 171/393 reads (44%) | SIFT tolerated, low confidence (0.62); PolyPhen probably damaging (0.979); catalogued as rs1558894064, COSV52146425; called by muse, mutect2, varscan2
- HDAC4 | c.1846G>A p.G616S | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.125); catalogued as rs1352142364; called by muse, mutect2, varscan2
- IGHV2-70 | c.147C>A p.S49R | Missense Mutation (SNP) | VAF 74/162 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs376260160; called by muse, varscan2
- IGKJ2 | c.33G>T p.E11D | Missense Mutation (SNP) | VAF 20/40 reads (50%) | catalogued as rs75187701; called by muse, varscan2
- IGKJ2 | c.32A>C p.E11A | Missense Mutation (SNP) | VAF 20/40 reads (50%) | catalogued as rs146019185; called by muse, varscan2
- IGLL5 | c.127G>A p.V43I | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); catalogued as rs6003368, COSV73248992, COSV73250942, COSV73250989, COSV73251049; called by muse, mutect2, varscan2
- IGLV3-1 | c.207T>G p.D69E | Missense Mutation (SNP) | VAF 95/231 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.166); catalogued as rs376313046; called by muse, varscan2
- IKBKE | c.1251C>A p.G417= | Splice Region (SNP) | VAF 58/165 reads (35%) | catalogued as rs782083272, COSV65624329; called by muse, mutect2, varscan2
- IL13RA2 | c.277G>T p.D93Y | Missense Mutation (SNP) | VAF 65/209 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.036); catalogued as COSV99682838; called by muse, mutect2, varscan2
- KIAA1217 | c.5626C>T p.L1876F | Missense Mutation (SNP) | VAF 252/600 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs375951552; called by muse, mutect2, varscan2
- MLH1 | c.1930G>C p.D644H | Missense Mutation (SNP) | VAF 100/255 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as CD093528; called by muse, mutect2, varscan2
- NYX | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 97/221 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs1255476959; called by muse, mutect2, varscan2
- PARD3B | c.784C>T p.L262F | Missense Mutation (SNP) | VAF 63/128 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759141232; called by muse, mutect2, varscan2
- PES1 | c.487C>T p.R163W | Missense Mutation (SNP) | VAF 72/167 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs747842532; called by muse, mutect2, varscan2
- PLSCR5 | c.32G>A p.R11K | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs1281889026; called by muse, mutect2, varscan2
- POT1 | c.820G>A p.G274R | Missense Mutation (SNP) | VAF 70/250 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1296966928, COSV100714174, COSV104423892; called by muse, mutect2, varscan2
- SDK1 | c.4010C>T p.S1337L | Missense Mutation (SNP) | VAF 9/200 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as rs1273485520, COSV67365196; called by muse, mutect2
- SLITRK1 | c.1001C>A p.P334H | Missense Mutation (SNP) | VAF 37/53 reads (70%) | SIFT deleterious (0.02); PolyPhen benign (0.227); catalogued as rs1394039996, COSV65673986, COSV65675543, COSV65676597; called by muse, mutect2, varscan2
- TPP2 | c.290T>C p.L97P | Missense Mutation (SNP) | VAF 8/117 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101060195; called by muse, mutect2
- TPP2 | c.1493G>A p.G498E | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101060390; called by muse, mutect2
- ABCA7 | c.3716T>G p.L1239R | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- ABCE1 | c.986T>G p.L329R | Missense Mutation (SNP) | VAF 63/119 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- AGMO | c.235G>A p.G79S | Missense Mutation (SNP) | VAF 14/330 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- AICDA | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- ASTE1 | c.461G>A p.C154Y | Missense Mutation (SNP) | VAF 12/342 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BAIAP2 | c.878A>T p.Q293L | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- CLSTN1 | c.1016C>T p.P339L (on ENST00000377298 / NM_001009566.3; = p.P329L on NM_014944.4) | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CNNM1 | c.2033A>C p.K678T | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- HS3ST4 | c.928A>G p.T310A | Missense Mutation (SNP) | VAF 76/172 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- IL23R | c.272del p.N91Tfs*23 | Frame Shift Del (DEL) | VAF 75/190 reads (39%) | called by mutect2, pindel, varscan2
- LAYN | c.52G>A p.G18R | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- MYC | c.793_795del p.V265del (on ENST00000377970; = p.V280del on NM_002467.6) | In Frame Del (DEL) | VAF 118/326 reads (36%) | called by pindel, varscan2
- NEXMIF | c.3007T>G p.S1003A | Missense Mutation (SNP) | VAF 104/225 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- PTK2 | c.3100T>G p.L1034V | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- RIN2 | c.767T>C p.M256T (on ENST00000255006 / NM_001242581.1; = p.M207T on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 79/184 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ROBO1 | c.2097A>T p.Q699H | Missense Mutation (SNP) | VAF 56/131 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- SGK1 | c.665A>G p.D222G | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- SMC5 | c.2089C>G p.L697V | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- TBC1D8B | c.662A>G p.H221R | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- TENM1 | c.5088G>A p.M1696I | Missense Mutation (SNP) | VAF 59/234 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TNNT1 | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); called by muse, mutect2
- TPP2 | c.374T>G p.L125R | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZBED8 | c.474dup p.Q159Tfs*13 | Frame Shift Ins (INS) | VAF 77/220 reads (35%) | called by mutect2, pindel, varscan2
- ZFR2 | c.1007C>T p.A336V | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZNF598 | c.1516G>T p.A506S | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ATRX | c.4047C>T p.D1349= | Silent (SNP) | VAF 67/133 reads (50%) | catalogued as rs199625659, COSV64874986, COSV64882477; ClinVar: likely benign; called by muse, mutect2, varscan2
- CFAP77 | c.387C>T p.D129= | Silent (SNP) | VAF 76/117 reads (65%) | catalogued as rs966873289, COSV58017394; called by muse, mutect2, varscan2
- HMCN2 | c.14352A>C p.P4784= | Silent (SNP) | VAF 79/262 reads (30%) | called by muse, mutect2, varscan2
- LCP2 | c.114G>A p.K38= | Silent (SNP) | VAF 84/213 reads (39%) | catalogued as rs1258998217, COSV50463060; called by muse, mutect2, varscan2
- NCKAP5 | c.1524C>T p.S508= | Silent (SNP) | VAF 43/121 reads (36%) | catalogued as rs765615880, COSV58483864; called by muse, mutect2, varscan2
- NOX4 | c.834T>G p.A278= | Silent (SNP) | VAF 52/101 reads (51%) | called by muse, mutect2, varscan2
- NPAS2 | c.1800C>A p.L600= | Silent (SNP) | VAF 45/114 reads (39%) | called by muse, mutect2, varscan2
- RIMS3 | c.861C>T p.L287= | Silent (SNP) | VAF 55/123 reads (45%) | catalogued as rs145116599; called by muse, mutect2, varscan2
- RNF128 | c.900T>C p.H300= (on ENST00000255499 / NM_194463.2; = p.H274= on NM_024539.3) | Silent (SNP) | VAF 64/205 reads (31%) | called by muse, mutect2, varscan2
- RXRG | c.891C>T p.D297= | Silent (SNP) | VAF 9/114 reads (8%) | called by muse, mutect2
- SSC5D | c.1620C>T p.T540= | Silent (SNP) | VAF 61/147 reads (41%) | catalogued as rs1052226850, COSV101047336; called by muse, mutect2, varscan2
- TRPV6 | c.2226C>T p.T742= | Silent (SNP) | VAF 113/374 reads (30%) | catalogued as rs569366787; called by muse, mutect2, varscan2
- TTN | c.90345G>A p.V30115= (on ENST00000591111; = p.V22691= on NM_003319.4) | Silent (SNP) | VAF 25/245 reads (10%) | called by muse, mutect2, varscan2
- ABRA | c.*646G>A | 3'UTR (SNP) | VAF 32/68 reads (47%) | called by muse, varscan2
- ALCAM | c.-330A>T | 5'UTR (SNP) | VAF 48/116 reads (41%) | called by muse, mutect2, varscan2
- ALK | chr2:29189564 T>C | 3'Flank (SNP) | VAF 140/315 reads (44%) | called by muse, mutect2, varscan2
- AP1M2 | c.*131C>T | 3'UTR (SNP) | VAF 16/55 reads (29%) | called by muse, mutect2
- AR | c.*4852A>G | 3'UTR (SNP) | VAF 15/31 reads (48%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021498 del G | 5'Flank (DEL) | VAF 102/292 reads (35%) | called by mutect2, pindel, varscan2
- BRI3BP | c.*4517C>T | 3'UTR (SNP) | VAF 54/142 reads (38%) | catalogued as rs1438497478; called by muse, mutect2, varscan2
- C3orf70 | c.*4911A>T | 3'UTR (SNP) | VAF 16/30 reads (53%) | called by muse, mutect2, varscan2
- CCL25 | c.*33A>G | 3'UTR (SNP) | VAF 71/251 reads (28%) | called by muse, mutect2, varscan2
- CRNKL1 | c.*63C>T | 3'UTR (SNP) | VAF 63/130 reads (48%) | called by muse, mutect2, varscan2
- DUOX1 | c.3424+152C>T | Intron (SNP) | VAF 20/52 reads (38%) | catalogued as rs762847716; called by muse, mutect2, varscan2
- DYNC1I2 | c.871-50C>T | Intron (SNP) | VAF 16/29 reads (55%) | called by muse, mutect2, varscan2
- FAM169B | n.782G>A | RNA (SNP) | VAF 53/107 reads (50%) | catalogued as rs1182536198; called by muse, mutect2, varscan2
- GPR37 | c.-543C>A | 5'UTR (SNP) | VAF 144/514 reads (28%) | called by muse, mutect2, varscan2
- HSPA1B | c.*250C>G | 3'UTR (SNP) | VAF 6/62 reads (10%) | called by muse, mutect2
- IBA57 | c.*5439T>A | 3'UTR (SNP) | VAF 24/79 reads (30%) | called by muse, mutect2, varscan2
- IGSF1 | c.667+112G>A | Intron (SNP) | VAF 22/75 reads (29%) | catalogued as rs1202257874; called by muse, mutect2, varscan2
- ITGB3BP | c.485-752C>T | Intron (SNP) | VAF 55/126 reads (44%) | called by muse, mutect2, varscan2
- KATNAL1 | c.*1839G>T | 3'UTR (SNP) | VAF 20/21 reads (95%) | called by muse, mutect2, varscan2
- MAGIX | c.196+254G>A | Intron (SNP) | VAF 6/15 reads (40%) | called by muse, mutect2
- MAN1A2 | c.*5383G>T | 3'UTR (SNP) | VAF 23/67 reads (34%) | called by muse, mutect2, varscan2
- MED17 | c.*232A>G | 3'UTR (SNP) | VAF 34/77 reads (44%) | called by muse, mutect2, varscan2
- MSC | c.*900C>T | 3'UTR (SNP) | VAF 99/226 reads (44%) | called by muse, mutect2, varscan2
- MSL3 | c.*166A>T | 3'UTR (SNP) | VAF 18/61 reads (30%) | called by muse, mutect2, varscan2
- MXRA8 | c.*526C>T | 3'UTR (SNP) | VAF 32/66 reads (48%) | called by muse, mutect2, varscan2
- NCAM2 | c.*1872C>A | 3'UTR (SNP) | VAF 6/78 reads (8%) | called by muse, mutect2
- P2RY12 | c.*374G>A | 3'UTR (SNP) | VAF 16/34 reads (47%) | called by muse, mutect2, varscan2
- PCDHAC1 | c.*2351G>T | 3'UTR (SNP) | VAF 36/70 reads (51%) | catalogued as COSV99151297; called by muse, mutect2, varscan2
- PHKA1 | c.*1379G>A | 3'UTR (SNP) | VAF 27/67 reads (40%) | called by muse, mutect2, varscan2
- PLA2G5 | c.*159C>T | 3'UTR (SNP) | VAF 41/104 reads (39%) | catalogued as rs947535871; called by muse, mutect2, varscan2
- PLPP3 | c.*1665A>G | 3'UTR (SNP) | VAF 43/92 reads (47%) | called by muse, mutect2, varscan2
- RB1CC1 | c.*1133G>A | 3'UTR (SNP) | VAF 3/45 reads (7%) | catalogued as rs928803055; called by muse, mutect2
- RGS4 | c.*1116T>C | 3'UTR (SNP) | VAF 57/86 reads (66%) | called by muse, mutect2, varscan2
- RIC1 | c.*2241_*2243del | 3'UTR (DEL) | VAF 34/120 reads (28%) | called by mutect2, pindel, varscan2
- RTL8B | c.*1134T>C | 3'UTR (SNP) | VAF 36/170 reads (21%) | called by muse, mutect2, varscan2
- RYR3 | c.10499+146G>C | Intron (SNP) | VAF 8/11 reads (73%) | called by muse, mutect2, varscan2
- SH3BGRL | c.*435A>T | 3'UTR (SNP) | VAF 17/50 reads (34%) | called by muse, mutect2, varscan2
- SIPA1L3 | c.*1356G>A | 3'UTR (SNP) | VAF 53/123 reads (43%) | called by muse, mutect2, varscan2
- SIX1 | c.*2163C>T | 3'UTR (SNP) | VAF 49/122 reads (40%) | called by muse, mutect2, varscan2
- SLC35E2B | c.*2409C>A | 3'UTR (SNP) | VAF 80/281 reads (28%) | called by muse, mutect2, varscan2
- SLC6A14 | c.*398C>A | 3'UTR (SNP) | VAF 42/111 reads (38%) | catalogued as COSV64141412; called by muse, mutect2, varscan2
- SLC6A9 | chr1:43995680 C>T | 3'Flank (SNP) | VAF 50/114 reads (44%) | catalogued as rs773448694; called by muse, mutect2, varscan2
- STPG2 | c.*504T>G | 3'UTR (SNP) | VAF 30/58 reads (52%) | called by muse, mutect2, varscan2
- TMEM106B | c.*364T>G | 3'UTR (SNP) | VAF 36/50 reads (72%) | called by muse, mutect2
- TMEM132D | c.1444-94A>G | Intron (SNP) | VAF 24/58 reads (41%) | called by muse, varscan2
- TMEM140 | chr7:135148016 A>C | 5'Flank (SNP) | VAF 52/171 reads (30%) | called by muse, mutect2, varscan2
- TRHDE | c.*204G>T | 3'UTR (SNP) | VAF 29/77 reads (38%) | called by muse, mutect2, varscan2
- TSC1 | c.*339T>G | 3'UTR (SNP) | VAF 53/183 reads (29%) | called by muse, mutect2, varscan2
- TXNDC5 | c.*961T>A | 3'UTR (SNP) | VAF 42/92 reads (46%) | called by muse, mutect2, varscan2
- ZIC4 | c.-15-1320G>T | Intron (SNP) | VAF 41/80 reads (51%) | called by muse, mutect2, varscan2
- ZIC4 | c.-16+869G>T | Intron (SNP) | VAF 51/133 reads (38%) | called by muse, mutect2, varscan2
- ZNF703 | c.-131G>A | 5'UTR (SNP) | VAF 40/97 reads (41%) | called by muse, mutect2, varscan2
- ZNF971P | n.541G>T | RNA (SNP) | VAF 3/45 reads (7%) | called by muse, mutect2
